Somatic mutation profile of cancer-model specimen HCM-BROD-0131-C25-85M (3D Organoid, passage 9; aliquot HCM-BROD-0131-C25-85M-01D-A79C-36), derived from the metastatic tumor of HCMI case HCM-BROD-0131-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; Age at diagnosis: 55.9 years (20,435 days).
Specimen HCM-BROD-0131-C25-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 9.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8278e291-b5bc-40d7-898c-db3bde431b00.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0131-C25-10A (Blood Derived Normal), aliquot HCM-BROD-0131-C25-10A-01D-A79C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/96f7ffc4-b933-458d-b62d-05d1a488e1d9

The open-access MAF lists 63 somatic variants for this specimen: 46 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 16, Nonsense Mutation 1, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RBPJ | c.193A>G p.R65G | Missense Mutation (SNP) | VAF 9/228 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1553878211, COSV60750623; ClinVar: likely pathogenic; called by muse, mutect2
- API5 | c.236G>C p.R79P | Missense Mutation (SNP) | VAF 82/302 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV66632804, COSV66634384; called by muse, mutect2, varscan2
- BMP6 | c.1159C>T p.R387C | Missense Mutation (SNP) | VAF 107/346 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1306853486, COSV51661769; called by muse, varscan2
- CAPN2 | c.289A>G p.I97V | Missense Mutation (SNP) | VAF 208/383 reads (54%) | SIFT tolerated (0.14); PolyPhen benign (0.142); catalogued as rs767061602; called by muse, varscan2
- ERG | c.1054G>A p.D352N (on ENST00000398919 / NM_001243428.1; = p.D328N on NM_004449.4) | Missense Mutation (SNP) | VAF 129/599 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55726685; called by muse, mutect2, varscan2
- FLG | c.4645C>G p.Q1549E | Missense Mutation (SNP) | VAF 122/444 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as rs1348207762, COSV64252606; called by muse, varscan2
- FLRT3 | c.313T>C p.Y105H | Missense Mutation (SNP) | VAF 23/220 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.356); catalogued as rs1486565329, COSV54009139, COSV99446755; called by muse, mutect2, varscan2
- FREM2 | c.7294C>T p.R2432W | Missense Mutation (SNP) | VAF 393/393 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as rs141120365, COSV54832682; called by muse, mutect2, varscan2
- IMPG2 | c.3172C>T p.P1058S | Missense Mutation (SNP) | VAF 15/343 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as rs1176943043, COSV104387278; called by muse, mutect2
- KLRF2 | c.169C>T p.H57Y | Missense Mutation (SNP) | VAF 105/370 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as rs575845984, COSV73374419; called by muse, mutect2, varscan2
- LARP6 | c.442A>G p.T148A | Missense Mutation (SNP) | VAF 86/200 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771510492; called by muse, mutect2, varscan2
- LRRIQ3 | c.1252C>T p.R418* | Nonsense Mutation (SNP) | VAF 176/272 reads (65%) | catalogued as rs753314061, COSV63041846; called by muse, varscan2
- MTHFD1 | c.2186A>G p.E729G | Missense Mutation (SNP) | VAF 71/167 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as rs758362102; called by muse, mutect2, varscan2
- MYO18A | c.3367C>T p.R1123C | Missense Mutation (SNP) | VAF 98/380 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs769998952; called by muse, varscan2
- NAALADL1 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 44/436 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762860964, COSV60525110; called by muse, mutect2
- OLFML3 | c.634C>A p.Q212K | Missense Mutation (SNP) | VAF 122/384 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.131); catalogued as rs1293253209; called by muse, varscan2
- PALM3 | c.1783G>A p.A595T (on ENST00000340790; = p.A610T on NM_001145028.2) | Missense Mutation (SNP) | VAF 204/423 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as rs773675549; called by muse, mutect2, varscan2
- PDE4A | c.2605G>A p.D869N (on ENST00000380702 / NM_001111307.2; = p.D630N on NM_006202.3) | Missense Mutation (SNP) | VAF 16/405 reads (4%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs1171633916; called by muse, mutect2
- PPP1R18 | c.1073C>T p.P358L | Missense Mutation (SNP) | VAF 82/773 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.011); catalogued as rs890499883; called by muse, mutect2, varscan2
- PTCH1 | c.1612G>A p.G538R | Missense Mutation (SNP) | VAF 14/476 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1347882326; called by muse, mutect2
- TP53BP2 | c.427C>T p.R143C (on ENST00000343537 / NM_001031685.3; = p.R14C on NM_005426.2) | Missense Mutation (SNP) | VAF 88/368 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs753184104; called by muse, varscan2
- ABI1 | c.1222G>C p.D408H | Missense Mutation (SNP) | VAF 200/295 reads (68%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.823); called by muse, varscan2
- AGAP6 | c.1556G>A p.S519N (on ENST00000374056 / NM_001365867.1; = p.S542N on NM_001077665.2) | Missense Mutation (SNP) | VAF 391/395 reads (99%) | SIFT deleterious (0.04); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- ATXN3L | c.910C>G p.P304A | Missense Mutation (SNP) | VAF 42/351 reads (12%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.065); called by muse, mutect2
- C2CD5 | c.61_63del p.A21del | In Frame Del (DEL) | VAF 353/708 reads (50%) | called by pindel, varscan2
- CACTIN | c.1204G>A p.V402M | Missense Mutation (SNP) | VAF 148/306 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CCR8 | c.104A>T p.K35M | Missense Mutation (SNP) | VAF 26/429 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.033); called by muse, mutect2
- CSMD3 | c.5529T>G p.S1843R (on ENST00000297405 / NM_001363185.1; = p.S1739R on NM_052900.3) | Missense Mutation (SNP) | VAF 75/572 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- DAXX | c.1103C>T p.A368V | Missense Mutation (SNP) | VAF 175/506 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- DIDO1 | c.2261T>C p.L754P | Missense Mutation (SNP) | VAF 16/383 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GAL3ST3 | c.850G>T p.A284S | Missense Mutation (SNP) | VAF 49/395 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- IPO7 | c.116T>G p.L39R | Missense Mutation (SNP) | VAF 12/288 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.367); called by muse, mutect2
- PAX6 | c.833C>T p.A278V | Missense Mutation (SNP) | VAF 172/431 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PFKFB1 | c.846G>T p.Q282H | Missense Mutation (SNP) | VAF 14/110 reads (13%) | PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- PFKFB1 | c.845A>G p.Q282R | Missense Mutation (SNP) | VAF 14/113 reads (12%) | PolyPhen benign (0.159); called by muse, mutect2, varscan2
- PIK3C2B | c.4856A>G p.E1619G | Missense Mutation (SNP) | VAF 21/530 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2
- PPM1K | c.860A>G p.H287R | Missense Mutation (SNP) | VAF 63/225 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- RANBP2 | c.8608T>G p.F2870V | Missense Mutation (SNP) | VAF 86/281 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RYR2 | c.7811A>T p.K2604M | Missense Mutation (SNP) | VAF 33/365 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2
- SPATA13 | c.1139T>C p.V380A | Missense Mutation (SNP) | VAF 38/293 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STAT5A | c.604A>G p.T202A | Missense Mutation (SNP) | VAF 42/567 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2
- TLE7 | c.526T>C p.C176R | Missense Mutation (SNP) | VAF 119/344 reads (35%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- TMEM176A | c.89C>A p.A30D | Missense Mutation (SNP) | VAF 52/727 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.514); called by muse, mutect2
- TRBC2 | c.464A>C p.K155T | Missense Mutation (SNP) | VAF 23/423 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- UTRN | c.3553C>T p.L1185F | Missense Mutation (SNP) | VAF 30/298 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- WNK1 | c.4846A>T p.T1616S (on ENST00000315939 / NM_018979.4; = p.T1369S on NM_014823.3) | Missense Mutation (SNP) | VAF 40/1004 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.836); called by muse, mutect2
- ACP5 | c.531C>T p.D177= | Silent (SNP) | VAF 140/312 reads (45%) | catalogued as rs369197756; called by muse, varscan2
- C2CD5 | c.69C>T p.D23= | Silent (SNP) | VAF 360/710 reads (51%) | catalogued as rs1364597300; called by muse, varscan2
- CACNA1H | c.1083C>T p.F361= | Silent (SNP) | VAF 143/448 reads (32%) | catalogued as rs763566127, COSV61990794; called by muse, mutect2, varscan2
- CASP10 | c.1236C>T p.I412= (on ENST00000272879 / NM_032974.5; = p.I369= on NM_001230.5) | Silent (SNP) | VAF 152/604 reads (25%) | catalogued as rs756348445, COSV53779104; called by muse, mutect2, varscan2
- DRD3 | c.849G>A p.R283= | Silent (SNP) | VAF 43/518 reads (8%) | catalogued as rs1421997801; called by muse, mutect2
- GRID1 | c.2001T>A p.T667= | Silent (SNP) | VAF 8/134 reads (6%) | called by muse, mutect2
- ITGA4 | c.2115C>T p.G705= | Silent (SNP) | VAF 19/262 reads (7%) | catalogued as rs764689926, COSV67896906; called by muse, mutect2
- LAMC3 | c.2391G>A p.P797= | Silent (SNP) | VAF 252/535 reads (47%) | catalogued as rs749823705, COSV100735949; called by muse, mutect2, varscan2
- NOG | c.249C>T p.P83= | Silent (SNP) | VAF 60/943 reads (6%) | catalogued as rs1271500840; called by muse, mutect2
- PCDHA6 | c.183G>A p.P61= | Silent (SNP) | VAF 71/418 reads (17%) | catalogued as rs1554131158; called by muse, mutect2, varscan2
- RPL21 | c.81G>A p.L27= | Silent (SNP) | VAF 85/196 reads (43%) | called by muse, mutect2, varscan2
- TBC1D1 | c.1062C>T p.C354= | Silent (SNP) | VAF 23/223 reads (10%) | catalogued as rs1560632963; called by muse, mutect2
- USH2A | c.12021C>T p.D4007= | Silent (SNP) | VAF 200/424 reads (47%) | catalogued as rs1387370996, COSV100236002, COSV56390348; called by muse, varscan2
- USP38 | c.567G>A p.R189= | Silent (SNP) | VAF 104/475 reads (22%) | catalogued as rs1373917884; called by muse, mutect2, varscan2
- ZNF233 | c.534C>T p.T178= | Silent (SNP) | VAF 29/389 reads (7%) | called by muse, mutect2
- ZNF316 | c.753C>T p.D251= | Silent (SNP) | VAF 178/347 reads (51%) | catalogued as rs1368874461; called by muse, varscan2
- TMEM71 | c.814+158C>T | Intron (SNP) | VAF 180/532 reads (34%) | catalogued as rs577561745, COSV63458731; called by muse, varscan2
